Somatic mutation profile of tumor specimen MMRF_1277_1_BM_CD138pos (aliquot MMRF_1277_1_BM_CD138pos_T1_KAS5U_L01651) from MMRF case MMRF_1277, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,488 days).
Specimen MMRF_1277_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b4e3aab-247a-4835-8cd5-4b2eae1a9e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1277_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1277_1_PB_Whole_C1_KAS5U_L01709; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde736c4-5a43-415f-a5f6-0572742851e8

The open-access MAF lists 125 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 39, Silent 16, Intron 13, 5'UTR 5, Nonsense Mutation 3, RNA 2, Frame Shift Del 1, 3'Flank 1, In Frame Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 274/382 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C5 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 106/261 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as COSV56327574; called by muse, mutect2, varscan2
- CPVL | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305561; called by muse, mutect2, varscan2
- FRY | c.7504C>T p.R2502C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs201153727; called by muse, mutect2, varscan2
- HIF3A | c.1937C>T p.P646L (on ENST00000377670 / NM_152795.4; = p.P577L on NM_022462.4) | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775640125; called by muse, mutect2, varscan2
- IGHV2-70 | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1381225694; called by muse, varscan2
- IGKV3-20 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748032359; called by muse, mutect2, varscan2
- IGLV3-1 | c.145A>C p.K49Q | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs192957059; called by muse, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, varscan2
- IGLV3-1 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs61731689; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, mutect2, varscan2
- KRTAP4-6 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.06); catalogued as rs564774866, COSV61982088; called by muse, mutect2, varscan2
- NECAB1 | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.037); catalogued as rs1184553762; called by muse, mutect2, varscan2
- NINL | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1357184820, COSV54002731; called by muse, mutect2, varscan2
- SAG | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as rs371502229, COSV68591185; called by muse, mutect2, varscan2
- SETD2 | c.4793G>A p.R1598Q | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57456666; called by muse, mutect2
- SMARCA5 | c.3088C>G p.P1030A | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1560822873; called by muse, mutect2, varscan2
- VPS52 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 25/286 reads (9%) | catalogued as rs1163234228, COSV71403408; called by muse, mutect2
- ARHGEF28 | c.2369A>C p.D790A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, varscan2
- C5 | c.2542T>G p.Y848D | Missense Mutation (SNP) | VAF 135/256 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLINT1 | c.973_980del p.D325* | Frame Shift Del (DEL) | VAF 31/48 reads (65%) | called by mutect2, pindel, varscan2
- CNDP2 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COLEC12 | c.1883T>C p.F628S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EYS | c.8693C>A p.T2898K (on ENST00000370621 / NM_001292009.1; = p.T2877K on NM_001142800.2) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EZH2 | c.1306G>A p.E436K (on ENST00000460911 / NM_001203247.2; = p.E441K on NM_004456.5) | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GPD1L | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- IGHV1-3 | c.7T>C p.W3R | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, varscan2
- IGHV2-70 | c.47G>C p.W16S | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.691); called by muse, varscan2
- IGHV2-70D | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- IGKV3-20 | c.335A>C p.Y112S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.092); called by mutect2, varscan2
- KCNC2 | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2
- KIFC2 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LAYN | c.862G>T p.D288Y (on ENST00000375615 / NM_001258390.1; = p.D280Y on NM_178834.5) | Missense Mutation (SNP) | VAF 68/484 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MUC16 | c.39829G>C p.D13277H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NBEAL2 | c.3465G>T p.E1155D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NIBAN1 | c.268T>G p.Y90D | Missense Mutation (SNP) | VAF 120/193 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN2 | c.4471G>A p.E1491K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PCDHA4 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLR3E | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PREX2 | c.1687T>G p.F563V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RENBP | c.462+5G>C | Splice Region (SNP) | VAF 32/53 reads (60%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.926G>T p.W309L (on ENST00000291707 / NM_053003.4; = p.W191L on NM_033329.2) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.10182T>A p.Y3394* (on ENST00000367255 / NM_182961.4; = p.Y3401* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- TBCCD1 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TDRD7 | c.2700_2709delinsC p.E900_P903delinsD | In Frame Del (DEL) | VAF 43/184 reads (23%) | called by pindel, varscan2*
- TRANK1 | c.7148A>G p.K2383R | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF529 | c.604A>C p.N202H | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZSWIM5 | c.2260C>A p.L754M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCB1 | c.9T>G p.L3= | Silent (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- CFAP57 | c.351A>G p.P117= | Silent (SNP) | VAF 154/340 reads (45%) | called by muse, mutect2, varscan2
- CRB1 | c.183T>C p.N61= | Silent (SNP) | VAF 58/182 reads (32%) | catalogued as rs1338529935, COSV100959595; called by muse, mutect2, varscan2
- CSMD3 | c.7536T>G p.L2512= (on ENST00000297405 / NM_001363185.1; = p.L2408= on NM_052900.3) | Silent (SNP) | VAF 37/72 reads (51%) | called by muse, mutect2, varscan2
- DMRTA1 | c.715C>T p.L239= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV57924342; called by muse, mutect2, varscan2
- HIVEP2 | c.810A>G p.E270= | Silent (SNP) | VAF 130/206 reads (63%) | called by muse, mutect2, varscan2
- HSPG2 | c.2406C>T p.D802= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs770590518, COSV65970805; called by muse, mutect2, varscan2
- IGHV2-70D | c.264C>A p.L88= | Silent (SNP) | VAF 40/45 reads (89%) | called by muse, varscan2
- NAA11 | c.474G>T p.L158= | Silent (SNP) | VAF 72/170 reads (42%) | catalogued as COSV54514696; called by muse, mutect2, varscan2
- PDE2A | c.1167C>A p.L389= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as rs149180422, COSV57803710; called by muse, mutect2, varscan2
- PLPP5 | c.198C>G p.L66= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV57670864, COSV57671343; called by muse, mutect2, varscan2
- RBM15 | c.1041A>G p.P347= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs1301856296; called by muse, mutect2, varscan2
- SEC23IP | c.651A>T p.G217= | Silent (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- TSHZ2 | c.384C>A p.V128= | Silent (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- VARS1 | c.2763T>G p.A921= | Silent (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- ZNF638 | c.267T>C p.F89= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs1227918432; called by muse, mutect2, varscan2
- ABCB8 | chr7:151046721 C>G | 3'Flank (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+8337G>A | Intron (SNP) | VAF 65/172 reads (38%) | catalogued as rs1340906516; called by muse, mutect2, varscan2
- ACSS3 | c.*4639C>T | 3'UTR (SNP) | VAF 30/322 reads (9%) | catalogued as rs529443610; called by muse, mutect2
- ADH5 | c.*13A>G | 3'UTR (SNP) | VAF 26/143 reads (18%) | called by muse, mutect2, varscan2
- ARF3 | c.*3172T>C | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- B4GALT6 | c.*896dup | 3'UTR (INS) | VAF 32/188 reads (17%) | catalogued as rs531317330; called by mutect2, varscan2
- BMT2 | c.*1016A>C | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- BUB1 | c.957+78T>G | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CERS2 | c.*812G>A | 3'UTR (SNP) | VAF 97/166 reads (58%) | called by muse, mutect2, varscan2
- CLK2 | c.*292T>C | 3'UTR (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- CXXC1 | c.640-33G>T | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- DERL3 | c.-7A>C | 5'UTR (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- DNAH5 | c.2053-35T>C | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- EXOC6B | c.*3249G>A | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- EYS | c.1766+3353T>C | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- FOXA2 | c.*444T>C | 3'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- FPGT | c.*424G>A | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- FUNDC2 | c.*2011A>T | 3'UTR (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- GFAP | c.-4C>T | 5'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- GLRX | c.*6+91T>G | Intron (SNP) | VAF 41/282 reads (15%) | called by muse, mutect2, varscan2
- GPATCH4 | c.32-58C>T | Intron (SNP) | VAF 68/441 reads (15%) | called by muse, mutect2, varscan2
- GRM6 | c.*130G>A | 3'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as rs1001643125; called by mutect2, varscan2
- H1-0 | c.*1027A>G | 3'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- H4-16 | c.*75_*78dup | 3'UTR (INS) | VAF 35/100 reads (35%) | called by pindel, varscan2
- H4-16 | c.*70G>C | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, varscan2
- HAL | c.1833+134C>T | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+36883C>T | Intron (SNP) | VAF 19/155 reads (12%) | catalogued as rs1298283483; called by muse, mutect2, varscan2
- HP | c.-95C>T | 5'UTR (SNP) | VAF 24/50 reads (48%) | catalogued as rs907724226; called by muse, varscan2
- IFFO2 | c.*2053G>A | 3'UTR (SNP) | VAF 40/122 reads (33%) | catalogued as rs1389071671; called by muse, mutect2, varscan2
- KCNG3 | c.*482T>C | 3'UTR (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- KCNG3 | c.-436C>A | 5'UTR (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2
- KLHL3 | c.*3C>T | 3'UTR (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- KLK7 | chr19:50983867 G>T | 5'Flank (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- LDAH | c.*1928A>C | 3'UTR (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- LFNG | c.582-38C>T | Intron (SNP) | VAF 41/106 reads (39%) | catalogued as rs770486288; called by muse, mutect2, varscan2
- LIMCH1 | c.936-5125A>C | Intron (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- LINC00637 | n.1688C>A | RNA (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- LY6K | c.*1730C>A | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- METTL15 | c.*382A>G | 3'UTR (SNP) | VAF 100/168 reads (60%) | called by muse, mutect2, varscan2
- MSANTD1 | c.*20G>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | catalogued as rs902132256; called by muse, mutect2, varscan2
- NLRX1 | c.*150G>A | 3'UTR (SNP) | VAF 76/227 reads (33%) | called by muse, mutect2, varscan2
- PCDH8 | c.*362C>T | 3'UTR (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- PCGF3 | c.*2879A>G | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*346A>C | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- PPFIA4 | c.*997C>T | 3'UTR (SNP) | VAF 129/222 reads (58%) | called by muse, mutect2, varscan2
- PPP1R3D | c.*670T>G | 3'UTR (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- PRR18 | c.*240T>A | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- RARA | c.179-6910_179-6908dup | Intron (INS) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- RASA1 | c.540-378A>C | Intron (SNP) | VAF 57/76 reads (75%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3379A>G | RNA (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- RWDD1 | c.*3439G>T | 3'UTR (SNP) | VAF 50/84 reads (60%) | called by muse, mutect2, varscan2
- SCIMP | c.-78G>T | 5'UTR (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- SGCZ | c.*282C>T | 3'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as rs987518674, COSV65993580; called by muse, mutect2, varscan2
- SH3D19 | c.*381G>A | 3'UTR (SNP) | VAF 51/95 reads (54%) | called by muse, mutect2, varscan2
- SHROOM1 | c.*204A>G | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- SNAP25 | c.*637A>C | 3'UTR (SNP) | VAF 66/141 reads (47%) | called by muse, varscan2
- SOCS5 | c.*385dup | 3'UTR (INS) | VAF 25/178 reads (14%) | catalogued as rs904905944; called by mutect2, pindel, varscan2
- TFRC | c.*2495A>G | 3'UTR (SNP) | VAF 20/119 reads (17%) | catalogued as rs934833174; called by muse, mutect2, varscan2
- WNT4 | c.*22G>A | 3'UTR (SNP) | VAF 33/50 reads (66%) | catalogued as rs1250753406; called by muse, mutect2, varscan2
- ZNF469 | c.*49C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs1270280243; called by muse, mutect2
- ZNF621 | c.*1611T>A | 3'UTR (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
